Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4635, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4635-01A (Primary Tumor).

tholgy Accessio

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE, FUHRMAN
NUCLEAR GRADE 3 (6.0 CM).

TUMOR CONFINED TO THE KIDNEY.

Margins of resection free of tumor.

Ureteral and vascular margins of resection free of tumor.

GROSS DESCRIPTION

(A) LEFT KIDNEY - A radical nephrectomy specimen (11.0 x 8.0 x 5.0 cm) including the left kidney (9.0 x 6.5 x 4.0 cm, a segment of renal artery and renal vein and ureter (5.0 cm in length and 0.5 cm in average diameter). No adrenal gland is identified.

There is a 6.0 x 5.0 x 5.0 cm well-circumscribed tumor in the mid pole of the kidney. The tumor is yellow-to-orange with focal areas of hemorrhage and necrosis, which are present predominantly in the center of the tumor. The tumor is confined to the kidney. The tumor is pushing the renal sinus. There is no invasion into the perinephric adipose tissue or renal pelvis. The tumor does not extend to Gerota's fascia.

The adjacent kidney parenchyma has multiple triangular shaped black discoloration in the cortex. The pelvicalyceal system is smooth and devoid of any lesions. No lymph nodes are identified in the hilum of the kidney.

A portion of the tumor and normal kidney has been submitted for research protocols. A portion of the tumor have been submitted for possible electron microscopy.

INK CODE: Black - renal capsule closest to the tumor.

SECTION CODE: A1, ureter and vascular margin; A2-A3, tumor with inked margin; A4, tumor; A5, tumor with adjacent pelvis; A6-A8, representative sections of tumor; A9, tumor and adjacent uninvolved kidney; A10-A11, uninvolved kidney with black discoloration.

CLINICAL HISTORY

Left renal mass.

Source: NCI Genomic Data Commons file 4b4640ba-3920-4c22-979c-b0012a3c93fa (TCGA-CJ-4635.023C84D4-F3AC-4AE8-920E-5095FB1FC375.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).